Gene-level copy-number profile of tumor specimen TCGA-A7-A6VY-01A from TCGA case TCGA-A7-A6VY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 48.3 years (17,640 days).
Specimen TCGA-A7-A6VY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.317d4bae-a933-41ef-ab8a-d4fbb6de5285.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A6VY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ea822a9-6923-441d-bdc1-61d6dfffc4ee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 24,140; copy number 2: 30,659; copy number 3: 3,867; copy number 4: 1,085; copy number 5: 35; copy number 6: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A6VY-01A-12D-A33D-01): tumor purity 0.59, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:154,190,730–154,876,792, 21 genes (within-gene range 0–1): GALNT10, SAP30L-AS1, HNRNPA3P7, AC008625.1, MIR1294, RN7SL655P, SAP30L, HAND1, AC026688.2, AC026688.1, CIR1P1, MIR3141, MIR1303, Y_RNA, LARP1, RN7SL803P, AC008379.1, FAXDC2, Metazoa_SRP, MIR378H, CNOT8.
- chr10:88,990,045–89,063,411, 6 genes: AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,212,606–234,683,176, 22 genes, copy number 5 (within-gene range 3–5): AL122008.3, AL122008.1, SLC35F3-AS1, AL122008.2, MIR4671, AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4.
- chr2:69,181,897–69,437,628, 6 genes, copy number 5: RNA5SP96, RNU6-1216P, AC112230.1, GFPT1, Y_RNA, NFU1.
- chr17:75,074,306–75,130,272, 4 genes, copy number 6: TRIM80P, SLC16A5, Y_RNA, ARMC7.

Autosomal genes at a single copy (total copy number 1): 22,382. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
